Somatic mutation profile of tumor specimen TCGA-CV-6941-01A (aliquot TCGA-CV-6941-01A-11D-1912-08) from TCGA case TCGA-CV-6941, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 51.5 years (18,812 days).
Specimen TCGA-CV-6941-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8593406e-ab84-4cbf-b1b6-dff88634d2d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6941-10A (Blood Derived Normal), aliquot TCGA-CV-6941-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92e5353a-5cb7-4e59-bc0c-c789e1dad548

The open-access MAF lists 161 somatic variants for this specimen: 117 protein-altering or splice-affecting, 38 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 38, Nonsense Mutation 7, Frame Shift Del 5, Intron 2, Splice Site 2, 5'Flank 2, Frame Shift Ins 1, Nonstop Mutation 1, Splice Region 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.4417C>T p.R1473* | Nonsense Mutation (SNP) | VAF 34/60 reads (57%) | catalogued as rs587784117, CM030072, COSV61786888; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAX6 | c.357C>A p.S119R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121907928, CD082176, CM013024, CM993965, COSV53794419, COSV99570036; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.529_546del p.P177_C182del | In Frame Del (DEL) | VAF 26/52 reads (50%) | hotspot (GDC flag); called by mutect2, varscan2
- ABCA7 | c.2890G>T p.D964Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99565052; called by muse, mutect2, varscan2
- ABCB7 | c.213A>T p.K71N (on ENST00000373394 / NM_001271696.3; = p.K72N on NM_004299.6) | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as COSV99503844; called by muse, mutect2, varscan2
- AFF2 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 74/107 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100648782, COSV60659728; called by muse, mutect2, varscan2
- ANK3 | c.8041C>T p.Q2681* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99778059; called by muse, mutect2, varscan2
- ANKIB1 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs774308207, COSV99728214; called by muse, varscan2
- ATF4 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV100307507; called by muse, mutect2, varscan2
- BICDL1 | c.885G>T p.R295S | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV101287126; called by muse, mutect2, varscan2
- C20orf204 | c.359T>A p.L120Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99411170; called by muse, mutect2
- CACNA1D | c.3995G>A p.R1332K (on ENST00000350061 / NM_001128840.3; = p.R1352K on NM_000720.4) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.557); catalogued as rs148194645; called by muse, mutect2, varscan2
- CARD17 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs865906757, COSV100995166; called by muse, mutect2, varscan2
- CD82 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1339483186, COSV57036117; called by muse, mutect2, varscan2
- CDHR1 | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV100258320; called by muse, mutect2, varscan2
- CDK11B | c.1468C>T p.L490F | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100477201; called by muse, mutect2, varscan2
- CES5A | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99307040; called by muse, mutect2, varscan2
- CKAP5 | c.4475A>T p.E1492V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV100370317; called by muse, mutect2, varscan2
- CLIC4 | c.372A>C p.K124N | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV100978098; called by muse, mutect2, varscan2
- CLMN | c.2780G>C p.S927T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100111962; called by muse, mutect2
- DEPDC7 | c.1448C>T p.S483L (on ENST00000241051 / NM_001077242.2; = p.S474L on NM_139160.2) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV99572547; called by muse, mutect2, varscan2
- DKK2 | c.197G>C p.S66T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV53398018; called by muse, mutect2, varscan2
- DLC1 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV99360679, COSV99362374; called by muse, mutect2
- DNAH11 | c.13478C>T p.T4493I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100176628; called by muse, mutect2, varscan2
- DNAH5 | c.9757G>A p.E3253K | Missense Mutation (SNP) | VAF 104/382 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99444373; called by muse, mutect2, varscan2
- DNAJC21 | c.1019A>G p.E340G | Missense Mutation (SNP) | VAF 129/279 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100331267; called by muse, mutect2, varscan2
- DRP2 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 97/142 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV100871768; called by muse, mutect2, varscan2
- EHMT2 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100977105; called by muse, mutect2, varscan2
- ELAVL1 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.418); catalogued as COSV100688096; called by muse, mutect2, varscan2
- FAM111A | c.1724G>C p.G575A | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100659317; called by muse, mutect2, varscan2
- FGFR3 | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.364); catalogued as rs954904695, COSV99600144; called by muse, mutect2, varscan2
- FNBP4 | c.2974G>T p.E992* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV54093323, COSV54093654, COSV99771372; called by muse, mutect2, varscan2
- GABRG3 | c.472A>T p.K158* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100404469; called by muse, varscan2
- GBF1 | c.4420G>A p.G1474R (on ENST00000369983 / NM_001377137.1; = p.G1473R on NM_004193.3) | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.899); catalogued as rs1217833812, COSV64142771; called by muse, mutect2, varscan2
- GRID1 | c.1175T>A p.V392D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100021624; called by muse, mutect2, varscan2
- GRIN2B | c.1011-1G>A p.X337_splice | Splice Site (SNP) | VAF 28/86 reads (33%) | catalogued as COSV101662889; called by muse, mutect2, varscan2
- GRIP2 | c.2099G>A p.G700D (on ENST00000619221; = p.G603D on NM_001080423.4) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99816887; called by muse, mutect2, varscan2
- HCAR2 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100186401; called by mutect2, varscan2
- HERC2 | c.14402T>G p.L4801R | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55318557; called by muse, mutect2, varscan2
- IGHV3-30 | c.232T>C p.Y78H | Missense Mutation (SNP) | VAF 49/885 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.048); catalogued as rs760505934; called by muse, mutect2
- KIF18B | c.2297C>T p.T766I (on ENST00000593135 / NM_001265577.2; = p.T778I on NM_001264573.2) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs765453241, COSV100191711; called by muse, mutect2, varscan2
- KIR2DL1 | c.817del p.N273Mfs*4 | Frame Shift Del (DEL) | VAF 29/137 reads (21%) | catalogued as rs1220669390; called by mutect2, pindel, varscan2
- KLF6 | c.620G>A p.C207Y | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99434894; called by muse, mutect2, varscan2
- KLHL15 | c.1346G>A p.S449N | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV100043943; called by muse, mutect2, varscan2
- KLHL17 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs767633652, COSV58532466; called by muse, mutect2, varscan2
- KLHL24 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.189); catalogued as rs761810211, COSV54426229; called by muse, mutect2, varscan2
- KLHL25 | c.1486A>T p.I496F | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs748560618, COSV100563426; called by muse, mutect2, varscan2
- KRT31 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs768070805, COSV52433777, COSV52434427; called by muse, mutect2, varscan2
- LGI4 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100032232; called by muse, mutect2, varscan2
- LRP1B | c.7520A>T p.N2507I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV101251504; called by muse, mutect2, varscan2
- MAMDC2 | c.150C>T p.G50= | Splice Region (SNP) | VAF 9/63 reads (14%) | catalogued as COSV101015175; called by muse, mutect2, varscan2
- MC5R | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 128/353 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.661); catalogued as rs1568532922, COSV100228903; called by muse, mutect2, varscan2
- MED12L | c.4535G>A p.R1512Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.388); catalogued as rs141691317; called by muse, varscan2
- MEGF9 | c.537C>A p.S179R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.207); catalogued as COSV100879296; called by muse, mutect2, varscan2
- MROH2B | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as COSV101270453; called by muse, mutect2, varscan2
- MYBPC1 | c.2813T>C p.V938A (on ENST00000550270 / NM_206820.2; = p.V945A on NM_002465.4) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100637717; called by muse, mutect2, varscan2
- MYCN | c.1129T>A p.S377T | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.985); catalogued as COSV99808010; called by muse, mutect2, varscan2
- MYH8 | c.3538G>C p.D1180H | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1411423641, COSV101238106; called by muse, mutect2, varscan2
- MYLK2 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); catalogued as COSV101044637, COSV65660038; called by muse, varscan2
- NT5C1B | c.635A>G p.N212S (on ENST00000359846 / NM_001199086.2; = p.N152S on NM_033253.4) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100409762; called by muse, mutect2, varscan2
- OR2AK2 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100823053; called by muse, mutect2
- OR51I2 | c.92T>G p.L31R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100413275; called by muse, mutect2, varscan2
- OR5H15 | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs773253290, COSV100736606, COSV62948324; called by muse, mutect2, varscan2
- OR5T3 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100282660; called by muse, mutect2, varscan2
- OSBPL1A | c.1910G>A p.R637Q (on ENST00000319481 / NM_080597.4; = p.R124Q on NM_018030.4) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100111035; called by muse, mutect2, varscan2
- PACSIN1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs1283413633, COSV99762842; called by muse, mutect2, varscan2
- PIK3R2 | c.1628A>T p.E543V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99717143; called by muse, mutect2, varscan2
- PLCB1 | c.1865T>C p.V622A | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100569197; called by muse, mutect2, varscan2
- PRR14 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV99788245; called by muse, mutect2
- PTGS1 | c.1178C>G p.S393C | Missense Mutation (SNP) | VAF 80/125 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99792867; called by muse, mutect2, varscan2
- RAB3IP | c.1019T>A p.I340N (on ENST00000550536 / NM_175623.4; = p.I324N on NM_022456.5) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99922897; called by muse, mutect2, varscan2
- RANBP9 | c.1366A>G p.T456A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV99163489; called by muse, mutect2, varscan2
- REXO4 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV64241795; called by muse, mutect2, varscan2
- RGS1 | c.505A>C p.T169P | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.942); catalogued as COSV100817381; called by muse, mutect2, varscan2
- RHOT2 | c.775A>G p.I259V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV53472394, COSV99552581; called by muse, mutect2, varscan2
- RPL22 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99329564; called by muse, mutect2, varscan2
- RPS6KA4 | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.892); catalogued as COSV99589724; called by muse, mutect2, varscan2
- SERPING1 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV99557793; called by muse, mutect2, varscan2
- SH2D1B | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100854740; called by muse, mutect2
- SIRPB1 | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99498138; called by muse, mutect2, varscan2
- SLC11A2 | c.1561A>T p.M521L (on ENST00000394904 / NM_001379455.1; = p.M492L on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100014442; called by muse, mutect2, varscan2
- SLC26A5 | c.1963G>T p.V655F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100098551; called by muse, mutect2, varscan2
- SLC44A5 | c.1034T>G p.F345C | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100900945; called by muse, mutect2, varscan2
- SOWAHC | c.1285_1286del p.S429Tfs*17 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs776237005; called by pindel, varscan2
- SPATA31D1 | c.2339T>C p.V780A | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs754380091, COSV61203054; called by muse, mutect2, varscan2
- STOX2 | c.1979G>A p.G660E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100408299; called by muse, mutect2, varscan2
- STPG4 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99681178; called by muse, mutect2, varscan2
- SYNE1 | c.22859G>C p.S7620T (on ENST00000367255 / NM_182961.4; = p.S7549T on NM_033071.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.969); catalogued as COSV99551617; called by muse, mutect2, varscan2
- SYT15 | c.271del p.L91Cfs*78 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs782517771, COSV104428148; called by mutect2, pindel
- TASOR | c.4751G>C p.S1584T (on ENST00000355628 / NM_001365636.2; = p.S1208T on NM_015224.3) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.053); catalogued as COSV100413612; called by muse, mutect2, varscan2
- TEX10 | c.1415C>G p.S472C | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100887580; called by muse, mutect2, varscan2
- TEX14 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199725150, CM1513545, COSV53617304, COSV99541269, COSV99541722; called by muse, mutect2, varscan2
- TGFBI | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs755263822, COSV100526191; called by muse, mutect2, varscan2
- TIMM17A | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100938958; called by muse, mutect2, varscan2
- TMEM108 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100418234; called by muse, mutect2, varscan2
- TMEM175 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as rs752018860, COSV99297483; called by muse, mutect2, varscan2
- TNN | c.2071C>A p.Q691K | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.314); catalogued as COSV99510985; called by muse, mutect2, varscan2
- TSHR | c.1929T>A p.Y643* | Nonsense Mutation (SNP) | VAF 58/160 reads (36%) | catalogued as COSV99990936; called by muse, mutect2, varscan2
- TSHR | c.1930G>T p.A644S | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99990937; called by muse, mutect2, varscan2
- TTYH2 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs368446841; called by muse, mutect2
- USP4 | c.1972+1G>C p.X658_splice | Splice Site (SNP) | VAF 5/8 reads (63%) | catalogued as COSV99648945; called by muse, mutect2
- VEZF1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV51969438; called by muse, mutect2, varscan2
- XYLT2 | c.1013A>G p.N338S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as rs200858180, COSV99190509; called by muse, mutect2
- YEATS2 | c.3753G>C p.E1251D | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV100527420; called by muse, mutect2, varscan2
- ZBTB9 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1403445693, COSV101221723; called by muse, mutect2, varscan2
- ZNF107 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.769); catalogued as rs757722609, COSV100788190, COSV61332048; called by muse, mutect2, varscan2
- ZNF485 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.898); catalogued as COSV100700143; called by muse, mutect2, varscan2
- ZNF573 | c.1262A>C p.K421T (on ENST00000536220 / NM_001172692.1; = p.K363T on NM_152360.3) | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100265403; called by muse, mutect2, varscan2
- ZNF596 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100261470; called by muse, mutect2, varscan2
- ZNF654 | c.2942G>C p.S981T | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100525588; called by muse, mutect2, varscan2
- ZNF764 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99410923; called by muse, mutect2, varscan2
- APOBR | c.219C>G p.S73R | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by mutect2, varscan2
- COPS4 | c.272dup p.I92Dfs*4 | Frame Shift Ins (INS) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- KLHDC8B | c.1060del p.V354Sfs*36 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | called by mutect2, pindel, varscan2
- RUNDC3B | c.1412_1420del p.T471_*474delinsR | Nonstop Mutation (DEL) | VAF 14/73 reads (19%) | called by mutect2, pindel, varscan2
- XPOT | c.1417del p.S473Qfs*9 | Frame Shift Del (DEL) | VAF 51/145 reads (35%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.2118G>A p.E706= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV56986181; called by muse, mutect2, varscan2
- AL121899.2 | c.1779G>A p.A593= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs201706734; called by muse, mutect2, varscan2
- ANO4 | c.2514A>C p.R838= (on ENST00000392977 / NM_001286615.2; = p.R803= on NM_178826.4) | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV100151712; called by muse, mutect2, varscan2
- ARFGEF1 | c.4551A>G p.L1517= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs145845893; called by muse, mutect2, varscan2
- CBX2 | c.930G>A p.K310= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99490716; called by muse, mutect2, varscan2
- CD163L1 | c.1755G>A p.L585= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1278456901, COSV58011560; called by muse, varscan2
- COL11A1 | c.5064A>G p.G1688= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100614870; called by muse, mutect2, varscan2
- COL25A1 | c.1014G>A p.G338= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs757440468, COSV101211131, COSV67649618; called by muse, mutect2, varscan2
- DEPDC1 | c.1590T>G p.A530= | Silent (SNP) | VAF 49/214 reads (23%) | catalogued as COSV100920194; called by muse, mutect2, varscan2
- DIP2C | c.2199G>C p.L733= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99789794; called by muse, mutect2, varscan2
- ELAVL4 | c.1089G>T p.L363= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100836512; called by muse, mutect2, varscan2
- GAS2L2 | c.501A>T p.T167= | Silent (SNP) | VAF 97/308 reads (31%) | called by muse, mutect2, varscan2
- GRID2 | c.552C>T p.F184= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs1353138332, COSV56266722; called by muse, mutect2, varscan2
- IGKV2D-29 | c.204T>C p.P68= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as COSV101534354; called by muse, mutect2, varscan2
- KRT72 | c.447G>A p.Q149= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV99537016, COSV99537115; called by muse, mutect2, varscan2
- MIER2 | c.870C>T p.F290= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99315931; called by muse, mutect2, varscan2
- MOCOS | c.1503C>T p.A501= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99732708; called by muse, mutect2, varscan2
- MYO7A | c.2628G>A p.E876= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs782747460, COSV101289018; called by muse, mutect2, varscan2
- NOSTRIN | c.459T>C p.L153= (on ENST00000317647 / NM_001039724.4; = p.L75= on NM_052946.3) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100473080; called by muse, mutect2, varscan2
- OGDH | c.2527C>A p.R843= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV99758248; called by muse, mutect2, varscan2
- OR2G6 | c.867C>A p.I289= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100598009, COSV58575457; called by muse, mutect2, varscan2
- OR51E2 | c.687C>T p.S229= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV101211300, COSV101211383; called by muse, mutect2, varscan2
- OTX1 | c.1050G>T p.R350= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99246127; called by muse, mutect2, varscan2
- PAMR1 | c.429C>T p.S143= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs1565342649, COSV99552043; called by muse, mutect2, varscan2
- PCDH10 | c.1407C>T p.D469= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV52095560; called by muse, mutect2, varscan2
- PCDH15 | c.114A>G p.G38= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV100214399; called by muse, mutect2, varscan2
- SAP130 | c.2241G>A p.A747= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs199719276; called by muse, mutect2, varscan2
- SCAF11 | c.1617A>G p.T539= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV101014055; called by muse, mutect2, varscan2
- SOX8 | c.981G>A p.S327= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs749349882, COSV99559092; called by muse, varscan2
- SPG7 | c.1866C>T p.A622= (on ENST00000268704; = p.A629= on NM_003119.4) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99244469; called by muse, mutect2, varscan2
- TASOR2 | c.3984G>A p.E1328= | Silent (SNP) | VAF 71/214 reads (33%) | catalogued as COSV100049913; called by muse, mutect2, varscan2
- TNS1 | c.4848G>A p.Q1616= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV99409719; called by muse, mutect2, varscan2
- WDR70 | c.762G>A p.K254= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as rs1236939946, COSV99457329; called by muse, mutect2, varscan2
- WNK2 | c.4440G>A p.P1480= (on ENST00000297954 / NM_001282394.1; = p.P1443= on NM_006648.3) | Silent (SNP) | VAF 9/9 reads (100%) | catalogued as rs966809807, COSV52958775; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2352C>T p.L784= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV99648170; called by muse, mutect2, varscan2
- ZNF16 | c.1083C>T p.S361= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs756197012, COSV99429377; called by muse, mutect2, varscan2
- ZNF205 | c.1314C>T p.H438= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV99530107; called by muse, mutect2, varscan2
- ZNF517 | c.762C>T p.V254= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100743422; called by muse, mutect2, varscan2
- ACTN1 | c.2361+468G>T | Intron (SNP) | VAF 21/36 reads (58%) | catalogued as COSV99517159; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822204 C>T | 5'Flank (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498056 C>G | 5'Flank (SNP) | VAF 10/79 reads (13%) | catalogued as rs775986221; called by muse, mutect2, varscan2
- HERC2P3 | n.870C>A | RNA (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- TRAJ6 | chr14:22543241 del G | 3'Flank (DEL) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- TTN | c.10360+5006G>T | Intron (SNP) | VAF 23/61 reads (38%) | catalogued as rs764591972, COSV100617478, COSV60152921; called by muse, mutect2, varscan2
